Surgical pathology report (de-identified scan), TCGA case TCGA-F6-A8O4, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Asterand, specimen TCGA-F6-A8O4-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumors is located in left Brain, Frontal Lobe, with 10x8x4cm in size, soft and brown-white surface, moderately-margin.

Microscopic Description: Tumor architecture is loosen, infiltrating in benign brain tissue, composed of gemiscyte groups intervening in spindle cells. Tumor nuclei are elongate and irregular, hyperchromatic with small nucleoli. Mitotic figures are present. Tumor has fibrillar background. Vasculae are hyperplastic. Tumor is necrotic and hemorrhage and invasion of lymphocytes.

Diagnosis Details: Astrocytoma, grade II

Comments:

Formatted Path Reports: Brain tumor checklist

Diagnosis: Astrocytoma of the brain

Tumor location: Brain, Frontal Lobe, Left

Tumor size: 10 x 8 x 4 cm

Tumor grade: Moderately differentiated

Diagnosis details:

Comments: None

ICD-O-3

Astrocytoma, grade II 940013
Site ^{to C6CE} Brain, supratentorial NOS C71.9
^{path} Brain, frontal lobe C71.1
Sp 11/26/13

Source: NCI Genomic Data Commons file 7c8306bf-dba7-42e2-8f8b-49109dd5e842 (TCGA-F6-A8O4.4CDE1CF9-1B5E-4838-8417-916F1E8E8D97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).